Surgical pathology report (de-identified scan), TCGA case TCGA-28-5214, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5214-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5214

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, LEFT TEMPORAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 95% of tumor cellularity

C. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 30% of tumor necrosis
- 95% of tumor cellularity

D. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 2% of tumor necrosis
- 95% of tumor cellularity

E. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 30% of tumor necrosis
- 95% of tumor cellularity

F. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 95% of tumor cellularity

G. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #6:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

H. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #7:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

I. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #8:

- Glioblastoma multiforme, WHO grade IV

Patient Case(s): [REDACTED]

Copy For: [REDACTED]

Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

- 3% of tumor necrosis
- 95% of tumor cellularity

J. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, NCI #9:

- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 95% of tumor cellularity

K. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY, CLINICAL TRIAL:

- Glioblastoma multiforme, WHO grade IV

L, M. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 70% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the loss of PTEN in this case suggests a diminished probability of response to EGFR-kinase inhibitors.

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of $\beta 1$ and $\beta 2$ in this tumor suggest the tumor aggressiveness intermediate between the $\beta 1 \downarrow$ (or normal)/ $\beta 2$ normal (or $\uparrow$) (the most favorable prognosis) and $\beta 1 \uparrow$ / $\beta 2 \downarrow$ (least favorable prognosis).

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED].

Cancer Res. [REDACTED]

Correspondingly, presence of a large fraction of cells immunonegative to pMAPK antibody in this case suggests a likelihood of this tumor being responsive to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Pre-operative diagnosis: Frontal glioma ✓

MICROSCOPIC FINDINGS:

Sections disclose infiltrating densely cellular proliferation of pleomorphic hyperchromatic angulate nuclei associated with numerous mitotic figures. The nuclei demonstrate high pleomorphism and multinucleation. Endothelial proliferation and necrosis are conspicuous.

IMMUNOHISTOCHEMISTRY:

Study // Antibody	Block	Result
-------------------	-------	--------

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

P53	M2	Up to 5% (1-3+)
Ki-67	M2	Up to 25%
MGMT	M2	Up to 70% (1-2+)
PTEN	M2	Loss (0-1+)
pMAPK	M2	Up to 10% of tumor nuclei and 20% of cytoplasm positive
Laminin beta-1 (8/411)	M2	Upregulated (2+)
Laminin beta-2 (9/421)	M2	Upregulated (2-3+)
EGFR by FISH	M2	Pending

GROSS:

A. LEFT TEMPORAL MASS

Labeled with the patient's name, labeled "left temporal mass", and received fresh for intraoperative consultation and subsequently submitted in formalin is a 1.1 x 0.7 x 0.2 cm aggregate of multiple soft pale tan-brown cortical tissue fragments with adherent blood clot. Entirely submitted.

Slide key:

- A1. Frozen remnant - multiple
- A2. Remaining tissue - multiple

B. LEFT TEMPORAL NCI #1

Labeled with the patient's name, labeled "left temporal NCI #1", and received in formalin is a 0.9 x 0.8 x 0.3 cm aggregate of multiple soft hemorrhagic pale tan-pink tissue fragments. Entirely submitted.

B1. Multiple

C. LEFT TEMPORAL NCI #2

Labeled with the patient's name, labeled "left temporal NCI #2", and received in formalin is a 1.0 x 0.6 x 0.3 cm aggregate of multiple soft hemorrhagic pale tan tissue fragments. Entirely submitted.

C1. Multiple

D. LEFT TEMPORAL NCI #3

Labeled with the patient's name, labeled "left temporal NCI #3", and received in formalin is a 0.9 x 0.6 x 0.2 cm aggregate of multiple soft pale tan hemorrhagic tissue. Entirely submitted.

D1. Multiple

E. LEFT TEMPORAL NCI #4

Labeled with the patient's name, labeled "left temporal NCI #4", and received in formalin is a 0.8 x 0.5 x 0.2 cm aggregate of multiple soft hemorrhagic pale tan tissue fragments. Entirely submitted.

E1. Multiple

F. LEFT TEMPORAL NCI #5

Labeled with the patient's name, labeled "left temporal NCI #5", and received in formalin is a 0.7 x 0.4 x 0.2 cm aggregate of multiple soft hemorrhagic pale tan tissue fragments. Entirely submitted.

F1. Multiple

G. LEFT TEMPORAL NCI #6

Labeled with the patient's name, labeled "left temporal NCI #6", and received in formalin is a 0.8 x 0.6 x 0.2 cm aggregate of multiple soft pale tan hemorrhagic tissue fragments. Entirely submitted.

G1. Multiple

H. LEFT TEMPORAL NCI #7

Labeled with the patient's name, labeled "left temporal NCI #7", and received in formalin is a 0.8 x 0.7 x 0.3 cm aggregate of soft pale tan hemorrhagic tissue. Entirely submitted.

H1. Multiple

[page 4 of 5]
addendum - Please See End of Report *****

report *****

Labeled with the patient's name, labeled "left temporal NCI #8", and received in formalin is a 1.0 x 0.8 x 0.2 cm aggregate of soft pale tan hemorrhagic tissue. Entirely submitted.

Labeled with the patient's name, labeled "left temporal NCI #9", and received in formalin is a 0.9 x 0.6 x 0.2 cm aggregate of multiple soft pale tan hemorrhagic tissue. Entirely submitted.

Labeled with the patient's name, labeled "left temporal trial", and received in formalin are two soft pale tan hemorrhagic cortical tissue fragments measuring 1.0 and 1.6 cm in greatest dimension amounting in aggregate to 2.1 x 0.7 x 0.3 cm. Entirely submitted.

Labeled with the patient's name, labeled "left temporal mass permanent", and received in formalin is a 3.5 x 2.4 x 1.6 cm aggregate of soft pale tan hemorrhagic cortical tissue. Entirely submitted.

L1-L3. Multiple each

Labeled with the patient's name, labeled "left temporal tumor permanent)", and received in formalin is a 3.6 x 3.1 x 1.2 cm portion of soft pink-tan hemorrhagic cortical tissue. Entirely submitted.

M1-M4. 2, 2, 2, 1

INTRAOPERATIVE CONSULTATION: _____

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN AND TP):

- Glioblastoma

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

[page 5 of 5]
PATIENT: [REDACTED]

***** Addendum - Please See End of Report *****

ACCESSION #: [REDACTED]

Tissue Block: [REDACTED]

RESULTS: POSITIVE for EGFR Amplification (See note below)

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies showed amplification of the EGFR gene with a 26.4 ratio of EGFR signals to the centromere signals in 87.5% of the nuclei examined.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $< 40\%$ of the cells.

References:

These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED]

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED]. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 5feb1e61-6c37-4337-98d9-c8892229ebeb (TCGA-28-5214.63A3775F-34E7-41A7-B021-666DD4528272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).